Gene-level copy-number profile of tumor specimen TCGA-55-7995-01A from TCGA case TCGA-55-7995, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.5 years (26,837 days).
Specimen TCGA-55-7995-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f437579a-6706-438e-a971-db42075008b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7995-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3d70de0-cdfe-454c-91b8-317f75e19637

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 6,921; copy number 2: 25,741; copy number 3: 17,604; copy number 4: 5,638; copy number 5: 3,048; copy number 6: 267; copy number 7: 444; copy number 8: 19; copy number 12: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7995-01A-11D-2183-01): tumor purity 0.49, ploidy 2.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:10,328,411–13,641,585, 27 genes (within-gene range 0–2): AP003900.1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P.
- chr21:19,593,841–25,135,247, 58 genes: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1.
- chr21:25,202,207–25,202,315, 1 gene: RNA5SP489.
- chr21:27,143,344–28,137,611, 11 genes (within-gene range 0–1): GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697.
- chr21:29,536,933–30,440,945, 21 genes (within-gene range 0–1): GRIK1, AP000238.1, GRIK1-AS1, AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,759 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,184,634–94,131,832, 15 genes, copy number 7: RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr3:116,965,112–198,222,513, 1,480 genes, copy number 5–7 (broad region; genes not listed).
- chr7:122,318,411–122,886,759, 1 gene, copy number 5 (within-gene range 3–5): CADPS2.
- chr7:122,676,580–123,535,077, 12 genes, copy number 5: AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P.
- chr12:66,767–31,327,058, 775 genes, copy number 5 (broad region; genes not listed).
- chr12:39,293,228–41,072,415, 20 genes, copy number 6 (within-gene range 3–6): KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1.
- chr14:89,124,871–89,619,149, 1 gene, copy number 5 (within-gene range 4–5): FOXN3.
- chr14:89,349,377–91,266,666, 43 genes, copy number 5: AL357093.2, AL357093.1, AL356805.1, AL137230.2, FOXN3-AS1, FOXN3-AS2, RN7SKP107, AL137230.1, Y_RNA, RN7SKP255, CHORDC2P, EFCAB11, RAB42P1, TDP1, KCNK13, GLRXP2, Y_RNA, PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3, TTC7B, AL096869.1, AL096869.2, AL139193.1, AL139193.2, AL122020.2, AL122020.1, LINC02321, RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, AL135818.3.
- chr14:92,116,122–106,875,071, 659 genes, copy number 5 (broad region; genes not listed).
- chr16:35,552,909–35,912,516, 30 genes, copy number 5: C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr19:28,949,437–30,713,538, 36 genes, copy number 5–12: AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr19:35,497,220–41,786,893, 345 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:41,829,692–44,305,046, 123 genes, copy number 5 (broad region; genes not listed).
- chr20:20,659,710–31,944,963, 219 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
